Somatic mutation profile of tumor specimen 0DTREH from CCDI case PBCJKA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 20.3 years (7,418 days).
Specimen 0DTREH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8a8e4cdc-6950-4bc3-be7f-c708883f2544.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DTREO (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2df69b55-53df-43e8-95b3-1f61608732b8

The open-access MAF lists 94 somatic variants for this specimen: 53 protein-altering or splice-affecting, 29 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 29, Intron 5, 5'UTR 4, Nonsense Mutation 3, 3'UTR 3, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 278/742 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- ABCA1 | c.1570A>G p.M524V | Missense Mutation (SNP) | VAF 61/431 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs935683226; called by muse, mutect2, varscan2
- C4orf54 | c.28C>G p.R10G | Missense Mutation (SNP) | VAF 63/770 reads (8%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.773); catalogued as rs758769785; called by muse, mutect2
- C6 | c.1559C>T p.P520L | Missense Mutation (SNP) | VAF 99/719 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV54708029, COSV54710265; called by muse, mutect2, varscan2
- CACNB2 | c.313G>T p.A105S (on ENST00000324631 / NM_201596.3; = p.A50S on NM_000724.4) | Missense Mutation (SNP) | VAF 44/566 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.422); catalogued as COSV56639921; called by muse, mutect2
- CHRNB2 | c.524C>T p.S175L | Missense Mutation (SNP) | VAF 299/421 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs75760566, COSV100872545; called by muse, mutect2, varscan2
- DDX18 | c.1873G>A p.V625I | Missense Mutation (SNP) | VAF 52/590 reads (9%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as rs561722336, COSV54305648; called by muse, mutect2
- FAM205A | c.2225C>A p.T742K | Missense Mutation (SNP) | VAF 50/352 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.047); catalogued as rs574131611; called by muse, mutect2
- GABRB2 | c.1267G>A p.G423R (on ENST00000274547; = p.G385R on NM_000813.3) | Missense Mutation (SNP) | VAF 127/1336 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.836); catalogued as rs78260275; called by muse, mutect2
- GCNA | c.918C>G p.D306E | Missense Mutation (SNP) | VAF 110/514 reads (21%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.024); catalogued as COSV65466740; called by muse, mutect2, varscan2
- GRIK1 | c.2000C>T p.T667M | Missense Mutation (SNP) | VAF 142/592 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754108610; called by muse, mutect2, varscan2
- MROH1 | c.4135G>A p.V1379M | Missense Mutation (SNP) | VAF 91/955 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1291536433; called by muse, mutect2
- PARD3B | c.640G>A p.G214R | Missense Mutation (SNP) | VAF 107/975 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62511065; called by muse, mutect2, varscan2
- PKP2 | c.2470G>C p.A824P | Missense Mutation (SNP) | VAF 54/721 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.132); catalogued as COSV50735844; called by muse, mutect2
- POLE | c.5494C>T p.L1832F | Missense Mutation (SNP) | VAF 103/718 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.78); catalogued as rs1456049352; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RANBP3 | c.1309G>A p.G437S (on ENST00000340578 / NM_007322.3; = p.G432S on NM_003624.3) | Missense Mutation (SNP) | VAF 32/476 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as COSV50380485; called by muse, mutect2
- RYR2 | c.7316C>G p.A2439G | Missense Mutation (SNP) | VAF 50/586 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs371753590; called by muse, mutect2
- TACR3 | c.830G>T p.G277V | Missense Mutation (SNP) | VAF 52/653 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.673); catalogued as COSV59208675; called by muse, mutect2
- TEDC2 | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 84/309 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.039); catalogued as rs752950230; called by muse, mutect2, varscan2
- THSD7B | c.613G>A p.A205T | Missense Mutation (SNP) | VAF 104/545 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV55684014; called by muse, mutect2, varscan2
- WNK4 | c.1079C>T p.A360V | Missense Mutation (SNP) | VAF 94/610 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1184025014, COSV53820360; called by muse, mutect2, varscan2
- ZBTB7B | c.1299C>A p.H433Q (on ENST00000292176; = p.H467Q on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/383 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.168); catalogued as rs1408413505; called by muse, mutect2, varscan2
- ADAM12 | c.1275G>T p.Q425H | Missense Mutation (SNP) | VAF 88/1205 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.681); called by muse, mutect2
- ADAMTS20 | c.1688A>G p.E563G | Missense Mutation (SNP) | VAF 80/560 reads (14%) | SIFT tolerated (0.79); PolyPhen benign (0); called by muse, mutect2, varscan2
- ASZ1 | c.991A>G p.K331E | Missense Mutation (SNP) | VAF 83/632 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- BTNL3 | c.380G>T p.W127L | Missense Mutation (SNP) | VAF 33/549 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.026); called by muse, mutect2
- CATSPERD | c.1278+1G>T p.X426_splice | Splice Site (SNP) | VAF 27/205 reads (13%) | called by muse, mutect2, varscan2
- CCDC18 | c.3880A>T p.K1294* (on ENST00000343253 / NM_001306076.1; = p.K1295* on NM_206886.4) | Nonsense Mutation (SNP) | VAF 28/297 reads (9%) | called by muse, varscan2
- CTNNA3 | c.2275C>A p.P759T | Missense Mutation (SNP) | VAF 77/666 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- DLK2 | c.584G>A p.R195H | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.659); called by muse, mutect2
- FCGBP | c.4394C>A p.S1465Y | Missense Mutation (SNP) | VAF 50/606 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- FGF16 | c.247G>A p.G83R | Missense Mutation (SNP) | VAF 253/284 reads (89%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- FILIP1 | c.1544T>G p.M515R | Missense Mutation (SNP) | VAF 122/528 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); called by muse, mutect2, varscan2
- HERPUD2 | c.1023T>A p.D341E | Missense Mutation (SNP) | VAF 100/1003 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2
- INTS6 | c.1608G>T p.L536F | Missense Mutation (SNP) | VAF 55/286 reads (19%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- ITGA9 | c.2855T>C p.V952A | Missense Mutation (SNP) | VAF 93/564 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- JAK2 | c.710T>A p.I237N | Missense Mutation (SNP) | VAF 118/452 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); called by mutect2, varscan2
- KLHDC3 | c.773A>G p.N258S | Missense Mutation (SNP) | VAF 264/612 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- OR5M11 | c.803A>T p.E268V | Missense Mutation (SNP) | VAF 136/628 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, varscan2
- PDE3B | c.1342C>A p.L448I | Missense Mutation (SNP) | VAF 185/595 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- POLR3E | c.400C>A p.Q134K | Missense Mutation (SNP) | VAF 74/547 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTX3 | c.1032C>A p.S344R | Missense Mutation (SNP) | VAF 181/540 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- RFX8 | c.1136G>A p.S379N (on ENST00000646446; = p.S308N on NM_001145664.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 162/695 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- RNF139 | c.25C>T p.Q9* | Nonsense Mutation (SNP) | VAF 60/543 reads (11%) | called by muse, mutect2, varscan2
- RPA4 | c.211G>A p.V71I | Missense Mutation (SNP) | VAF 35/281 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- RSF1 | c.3294C>A p.S1098R | Missense Mutation (SNP) | VAF 53/437 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- RTP4 | c.330C>G p.S110R | Missense Mutation (SNP) | VAF 76/477 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- SALL4 | c.2799G>T p.L933F | Missense Mutation (SNP) | VAF 98/605 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SMCR8 | c.2492C>G p.A831G | Missense Mutation (SNP) | VAF 51/409 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SORCS1 | c.152C>A p.S51* | Nonsense Mutation (SNP) | VAF 37/322 reads (11%) | called by muse, mutect2, varscan2
- TDRD15 | c.4886A>G p.E1629G | Missense Mutation (SNP) | VAF 36/882 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); called by muse, mutect2
- TNIP1 | c.1036C>A p.Q346K | Missense Mutation (SNP) | VAF 128/1071 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- ZBBX | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 78/364 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AC092718.8 | c.186A>G p.T62= | Silent (SNP) | VAF 36/480 reads (8%) | called by muse, mutect2
- APC2 | c.4869G>A p.R1623= | Silent (SNP) | VAF 52/276 reads (19%) | catalogued as rs979499942; called by muse, mutect2, varscan2
- ATP2B2 | c.111G>T p.L37= | Silent (SNP) | VAF 89/492 reads (18%) | called by muse, mutect2, varscan2
- CACNA1G | c.5283C>T p.G1761= | Silent (SNP) | VAF 100/917 reads (11%) | catalogued as rs775368690; called by muse, mutect2, varscan2
- CBARP | c.207C>T p.D69= (on ENST00000382477; = p.D75= on NM_152769.3) | Silent (SNP) | VAF 30/486 reads (6%) | catalogued as rs1036676144; called by muse, mutect2
- CCDC80 | c.480G>A p.S160= | Silent (SNP) | VAF 67/372 reads (18%) | catalogued as rs1163077370, COSV99244665; called by muse, mutect2, varscan2
- CDK11A | c.1815G>A p.T605= (on ENST00000378633 / NM_001313896.2; = p.T602= on NM_024011.4) | Silent (SNP) | VAF 43/570 reads (8%) | catalogued as rs374131092; called by muse, mutect2
- CFAP221 | c.1546C>A p.R516= | Silent (SNP) | VAF 85/1014 reads (8%) | called by muse, mutect2
- DMGDH | c.1602A>G p.L534= | Silent (SNP) | VAF 148/707 reads (21%) | catalogued as rs1220978566; called by muse, mutect2, varscan2
- DNAH7 | c.6477G>C p.L2159= | Silent (SNP) | VAF 86/789 reads (11%) | catalogued as rs1559169030, COSV56771478; called by muse, mutect2, varscan2
- FA2H | c.543G>A p.L181= | Silent (SNP) | VAF 59/677 reads (9%) | catalogued as rs750511573, COSV54725237; called by muse, mutect2
- FCGBP | c.699G>A p.T233= | Silent (SNP) | VAF 45/409 reads (11%) | catalogued as rs144462134; called by muse, mutect2, varscan2
- IL1R1 | c.1704C>A p.L568= | Silent (SNP) | VAF 146/573 reads (25%) | catalogued as COSV52105713; called by muse, mutect2, varscan2
- KIAA0586 | c.3579C>T p.A1193= (on ENST00000619416 / NM_001244190.2; = p.A1132= on NM_014749.5) | Silent (SNP) | VAF 88/399 reads (22%) | catalogued as rs367676896; called by muse, mutect2, varscan2
- MYO3A | c.4014A>G p.P1338= | Silent (SNP) | VAF 40/787 reads (5%) | called by muse, mutect2
- MYOZ3 | c.633C>A p.P211= | Silent (SNP) | VAF 373/473 reads (79%) | catalogued as COSV51739917; called by muse, mutect2, varscan2
- NEB | c.5274C>T p.T1758= | Silent (SNP) | VAF 101/1026 reads (10%) | called by muse, mutect2, varscan2
- OBSCN | c.8514G>C p.V2838= | Silent (SNP) | VAF 65/734 reads (9%) | called by muse, mutect2
- OSBPL7 | c.2187C>T p.D729= | Silent (SNP) | VAF 67/381 reads (18%) | called by muse, mutect2, varscan2
- PMFBP1 | c.117C>T p.T39= | Silent (SNP) | VAF 100/672 reads (15%) | catalogued as rs1035859622; called by muse, mutect2, varscan2
- PSMC2 | c.1161C>T p.S387= | Silent (SNP) | VAF 63/544 reads (12%) | catalogued as rs183253099, COSV53008068, COSV99035255; called by muse, mutect2, varscan2
- PSMG4 | c.141G>T p.L47= | Silent (SNP) | VAF 59/253 reads (23%) | called by muse, mutect2, varscan2
- RNF115 | c.189A>C p.I63= | Silent (SNP) | VAF 88/922 reads (10%) | called by muse, mutect2
- SLC4A10 | c.3294G>T p.L1098= (on ENST00000446997 / NM_001354461.2; = p.L1068= on NM_022058.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 94/849 reads (11%) | catalogued as COSV99762744; called by muse, mutect2, varscan2
- SOX17 | c.1068G>T p.G356= | Silent (SNP) | VAF 30/370 reads (8%) | called by muse, mutect2
- SYCP2L | c.1983A>T p.S661= | Silent (SNP) | VAF 76/810 reads (9%) | called by muse, mutect2
- TECTA | c.774T>C p.N258= | Silent (SNP) | VAF 268/595 reads (45%) | catalogued as rs761999813; called by muse, mutect2, varscan2
- VPS41 | c.1362A>G p.P454= | Silent (SNP) | VAF 48/822 reads (6%) | called by muse, mutect2
- ZNF790 | c.1413T>A p.I471= | Silent (SNP) | VAF 77/1049 reads (7%) | called by muse, mutect2
- AC010255.2 | c.-10T>G | 5'UTR (SNP) | VAF 79/741 reads (11%) | called by muse, mutect2, varscan2
- AKT1S1 | c.-8+547_-8+551del | Intron (DEL) | VAF 22/216 reads (10%) | called by mutect2, varscan2
- ARF3 | c.-54C>A | 5'UTR (SNP) | VAF 16/144 reads (11%) | catalogued as COSV99873099; called by muse, mutect2, varscan2
- BBOF1 | c.*81A>T | 3'UTR (SNP) | VAF 24/532 reads (5%) | called by muse, mutect2
- CDH10 | c.-81C>T | 5'UTR (SNP) | VAF 16/129 reads (12%) | catalogued as COSV100053469; called by muse, mutect2, varscan2
- CYP20A1 | c.*53A>T | 3'UTR (SNP) | VAF 19/134 reads (14%) | catalogued as rs1322485340, COSV61909402; called by muse, mutect2, varscan2
- HEPACAM | c.427+18G>A | Intron (SNP) | VAF 30/334 reads (9%) | called by muse, mutect2
- KLK14 | c.*11+20C>A | Intron (SNP) | VAF 65/234 reads (28%) | called by muse, mutect2, varscan2
- LINGO2 | c.*9C>A | 3'UTR (SNP) | VAF 75/351 reads (21%) | catalogued as COSV100430267; called by muse, mutect2, varscan2
- NLRP8 | c.-41C>A | 5'UTR (SNP) | VAF 12/103 reads (12%) | catalogued as COSV99405730; called by muse, varscan2
- SEL1L2 | c.1947+59G>T | Intron (SNP) | VAF 61/523 reads (12%) | called by muse, mutect2, varscan2
- SIPA1L2 | c.4941-48G>T | Intron (SNP) | VAF 22/280 reads (8%) | catalogued as rs1156756054; called by muse, mutect2
